Surgical pathology report (de-identified scan), TCGA case TCGA-MY-A5BD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Montefiore Medical Center, specimen TCGA-MY-A5BD-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Requested By [REDACTED]

Ordered By [REDACTED]

ICD-C-3

Carcinoma, Squamous cell NOS
8070/3

Site: Cervix Uteri, Cervix
C53.9

9/11/13

Surg Path Case - STATUS: Final

**SEE NOTE

Collect/Perform:

Ordered Date:

Department: PATH

Physician Who Performed Procedure:

Requesting Physician:

Attending Pathologist

DIAGNOSIS:

1. Lymph nodes, right common iliac, biopsy:
- Three lymph nodes; no tumor seen (0/3).
2. Lymph nodes, right obturator, biopsy:
- Two lymph nodes; no tumor seen (0/2).
3. Lymph node, left external iliac, biopsy:
- One lymph node; no tumor seen (0/1).
4. Lymph nodes, right obturator, biopsy:
- Six lymph nodes; no tumor seen (0/6).
5. Lymph nodes, left external iliac, biopsy:
- Fourteen lymph nodes; no tumor seen (0/14).
6. Uterus, cervix, and bilateral adnexa, radical hysterectomy and salpingo oophorectomy:
- Invasive squamous cell carcinoma of cervix, 7.8 cm, well to moderately differentiated, extending to endometrial cavity, and invading through the cervical wall superficially into the parametrium (see FULL REPORT below).
- Cervical intraepithelial neoplasia III/carcinoma in situ arising in a background of squamous metaplasia of adjacent endocervical mucosa.
- Foci of lymphovascular invasion seen.

[page 2 of 5]
Patient Name: [REDACTED]

Requested By:

Ordered By:

- The carcinoma is minimally transected at the inked and cauterized parametrial margin (slide 6H).
- The resection margins of vaginal cuff are negative for carcinoma.
- AJCC Pathologic Staging: pT2b NO M-n/a (FIGO IIB)

FULL REPORT (incorporates relevant findings from all parts):

- Histologic Type of Tumor: Squamous cell carcinoma
- Histologic Grade of Tumor: G1 - G2; well to moderately
- Tumor Site: Four quadrants with the right superior quadrant being dominant (9:00 - 12:00).
- Tumor Size:
- Greatest dimension: 7.8 cm; other two dimensions: 4.1 x 2.0 cm
- Other Organs Present: Uterine corpus, bilateral ovaries and fallopian tubes.
- Extent of Invasion: Invades through the cervical wall into parametrium (slides 6K, 6AK), and extends to lower uterine segment.
- Margins: Positive for invasive carcinoma
- Positive margin, or margin closest to invasive carcinoma: Parametrial margin near 6:00 (slide 6H)
- Distance of invasive carcinoma to closest margin: 0 mm
- Carcinoma In-Situ: Present
- Venous/Lymphatic (Large/Small Vessel) Invasion: Present
- Distant Metastasis: Cannot be assessed
- Regional lymph nodes (# positive/# examined): 0/26
- Additional Pathologic Findings: Atrophic endometrium; bilateral fallopian tubes and ovaries without significant histopathologic findings.
- AJCC Pathologic Staging: pT2b NO M-n/a (FIGO IIB)

COMMENT: None

CLINICAL INFORMATION:

Preop diagnosis of cervical cancer.

GROSS DESCRIPTION:

1. The specimen is received fresh for frozen section and labeled "right common iliac lymph node". The specimen consists of a yellow tan, lobulated portion of adipose tissue measuring 4.5 x 2.0 x 1.0 cm. The specimen is palpated to reveal two lymph nodes measuring 0.7 and 2.3 cm in greatest dimension. The specimen is submitted entirely in four cassettes as follows:

[page 3 of 5]
Patient Name: [REDACTED]

Requested By: [REDACTED]

Ordered By: [REDACTED]

larger lymph node

C: smaller lymph node

D: adipose tissue

Intraoperative report: Two lymph nodes; no tumor seen.

2. The specimen is received fresh for frozen section and labeled "right obturator lymph node". The specimen consists of a lymph node measuring 2.4 x 1.4 x 1.2 cm. The specimen is submitted entirely in three cassettes follows:

: one matted lymph node

C: adipose tissue

Intraoperative report: Two lymph nodes. No tumor seen.

3. The specimen is received fresh for frozen section and labeled "left external iliac pelvic lymph node". The specimen consists of one ovoid, hemorrhagic lymph node measuring 3.5 x 2.0 x 1.2 cm. The specimen is bisected and submitted entirely in two cassettes labeled

Intraoperative report: One lymph node. No tumor seen.

4. The specimen is received fresh and labeled "right obturator lymph node". The specimen consists of multiple, yellow-tan, lobulated portions of adipose tissue measuring 8.2 x 5.0 x 1.8 cm in aggregate. The specimen is palpated to reveal six possible lymph nodes ranging from 0.8 to 3.0 cm in greatest dimension. The specimen is submitted entirely in nine cassettes as follows:

4A: Two possible lymph nodes

4B: two possible lymph nodes

4C-4D: one lymph node bisected

4E-4F: one lymph node bisected

4G-4I: adipose tissue

5. The specimen is received fresh and labeled "left external iliac lymph node". The specimen consists of multiple, pink-tan, lobulated portions of adipose tissue measuring 9.0 x 5.0 x 1.8 cm in aggregate. The specimen is palpated to reveal 10 possible lymph nodes ranging from 0.5 to 3.1 cm in greatest dimension. The specimen is submitted entirely in 11 cassettes as follows:

5A: Four possible lymph nodes

5B: two possible lymph nodes

5C: one lymph node bisected

5D: one lymph node bisected

[page 4 of 5]
Patient Name: [REDACTED]

Requested By:

Ordered By: k

5E-5F: one lymph node bisected
5G-5H: one lymph node bisected
5I-5K: adipose tissue

6. The specimen is received fresh and labeled "uterus tubes/ovaries/parametrium/vagina inked margins and send for tumor studies". The specimen consists of a total hysterectomy specimen measuring 10.0 cm from fundus to cervical mucosa, 4.3 cm from cornu to cornu and 3.0 cm from anterior to posterior. The attached cervix measures 4.5 x 4.0 x 4.0 cm with a rim of vaginal cuff. The os is slit-like and measures 0.8 cm. Located at the three o'clock to nine o'clock aspect is a pink-tan, bosselated, protruding mass measuring 2.0 x 1.5 cm. The anterior is inked green and the posterior is inked black. A 0.6 cm portion of taken for research from the nine o'clock aspect. The specimen is opened to reveal the mass grossly extends the entire length of the cervix and into the uterus for an overall measurement of 7.8 x 4.1 x 2.0 cm. The triangular endometrial cavity measures 6.0 x 2.0 cm and the distal portion is distorted by the mass. The specimen is serially sectioned to reveal the mass grossly extends to the posterior margin (from approximately 6 o'clock to the 10 o'clock) and 0.1 cm from the anterior margin.

The attached right adnexa is composed of a fimbriated fallopian tube measuring 1.0 x 0.6 x 0.5 cm and an attached, cerebriform ovary measuring 2.7 x 1.4 x 1.0 cm. The fallopian tube is serially sectioned to reveal a pinpoint lumen. The ovary is serially sectioned to reveal normal ovarian parenchyma with a corpus albicans.

The attached left adnexa are composed of a fimbriated fallopian tube measuring 7.5 x 0.5 x 0.5 cm and a tan-pink, cerebriform ovary measuring 2.7 x 1.5 x 1.0 cm. The fallopian tube is serially sectioned to reveal a pinpoint lumen. The ovary is serially sectioned to reveal normal ovarian parenchyma with a corpus albicans.

Representative sections are submitted in 41 cassettes as follows (cervix and vaginal cuff submitted entirely):

6A-6C: cervix with attached vaginal cuff, 12 o'clock to three o'clock
6D-6G: cervix with attached vaginal cuff, three o'clock to six o'clock
6H-6M: cervix with attached vaginal cuff, six o'clock to nine o'clock
6N-6S: cervix with attached vaginal cuff, nine o'clock to 12 o'clock
(6N-6O: one slice)
6T: left adnexa
6U-6X: left parametrium
6Y: right adnexa

4 of 5

[page 5 of 5]
Patient Name: [REDACTED]
Requested By: [REDACTED]
Ordered By: [REDACTED]

- 6Z-6AE: right parametrium
- 6AF-6AG: anterior lower uterine segment (representative sections)
- 6AH-6AI: anterior endomyometrium
- 6AJ-AM: posterior lower uterine segment (representative sections)
- 6AN-6AO: posterior endomyometrium

** Electronic Signature **

**Electronically Signed Out by

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the final diagnosis(es).

The Attending Pathologist reviewed this case and made the diagnosis.

Where applicable, immunohistochemistry and in situ hybridization tests were developed and the performance characteristics determined by the Immunohistochemistry Laboratory, These tests have not been cleared or approved by the US Food and Drug Administration and the results should be correlated with other clinical and laboratory data. Appropriate controls were performed for all immunohistochemistry, in situ hybridization and histochemical tests.

50F5

Source: NCI Genomic Data Commons file 24c6a11f-ee12-4ebc-a64d-68e3ce2a38bb (TCGA-MY-A5BD.4BCA8C55-997E-4700-A12C-B520575C3608.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).